Gene-level copy-number profile of tumor specimen TCGA-A6-5660-01A from TCGA case TCGA-A6-5660, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Ascending colon; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 73.4 years (26,803 days).
Specimen TCGA-A6-5660-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-COAD.2efde02d-8554-4ec2-a132-62e8af27413e.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-A6-5660-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2 (sample pair TCGA-A6-5660-01A|TCGA-A6-5660-10A); ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/279da891-c5cf-409f-8013-304fdec6d3b4

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 793; copy number 2: 10,419; copy number 3: 19,074; copy number 4: 20,386; copy number 5: 3,556; copy number 6: 967; copy number 7: 845; copy number 8: 1,477; copy number 9: 1,882; copy number 10: 323; copy number 13: 67; copy number 14: 30.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-A6-5660-01A-01D-1649-01): tumor purity 0.88, ploidy 3.15, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 2,302 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:49,850,421–65,802,067, 348 genes, copy number 9 (within-gene range 5–9) (broad region; genes not listed).
- chr8:46,028,804–145,066,685, 1,534 genes, copy number 9 (broad region; genes not listed).
- chr20:30,377,372–34,927,962, 146 genes, copy number 10–13 (within-gene range 5–13) (broad region; genes not listed).
- chr20:43,590,937–53,875,557, 274 genes, copy number 10–14 (within-gene range 8–14) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 793. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
